Somatic mutation profile of tumor specimen TCGA-OD-A75X-06A (aliquot TCGA-OD-A75X-06A-12D-A32N-08) from TCGA case TCGA-OD-A75X, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.7 years (26,540 days).
Specimen TCGA-OD-A75X-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86fafbf0-3846-4339-aad4-d29a2798b344.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OD-A75X-10A (Blood Derived Normal), aliquot TCGA-OD-A75X-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f8d17f5-3250-421b-8c17-5dbb91a79c37

The open-access MAF lists 1,253 somatic variants for this specimen: 832 protein-altering or splice-affecting, 395 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 746, Silent 395, Nonsense Mutation 47, Splice Region 14, Intron 12, Splice Site 11, Frame Shift Del 6, RNA 4, 5'Flank 4, 5'UTR 3, Translation Start Site 3, 3'Flank 2.

Variants (750 of 1,253; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1567310537, COSV99190950; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.145A>T p.K49* (on ENST00000399959; = p.K50* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 40/41 reads (98%) | catalogued as rs1064796382, COSV101302445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 47/117 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs763413735, COSV59534728; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516792, CM071852, CM073191, COSV61068422, COSV61068985, COSV61070219; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NARS2 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 48/100 reads (48%) | catalogued as rs1057524183, COSV99807227; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 29/36 reads (81%) | hotspot (GDC flag); catalogued as rs587782607, CM116000, COSV100909697, COSV64292178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A3 | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 51/123 reads (41%) | catalogued as rs1018933248, COSV60641463; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 41/48 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TRPM3 | c.979+17799C>T | Intron (SNP) | VAF 119/134 reads (89%) | catalogued as rs767146880, CR156853, COSV100677419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1546G>A p.E516K (on ENST00000373993 / NM_138932.2; = p.E508K on NM_014576.4) | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs765124661, COSV50959265; called by muse, mutect2, varscan2
- ABCA13 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV101330050; called by muse, mutect2, varscan2
- ABCA13 | c.9406G>A p.E3136K | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0.019); catalogued as COSV71289134; called by muse, mutect2, varscan2
- ABCD2 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429506; called by muse, mutect2, varscan2
- ABTB1 | c.444G>A p.W148* (on ENST00000232744 / NM_172027.3; = p.W6* on NM_032548.3) | Nonsense Mutation (SNP) | VAF 46/106 reads (43%) | catalogued as COSV99229842; called by muse, mutect2, varscan2
- AC098582.1 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs773079685, COSV99985621; called by muse, mutect2, varscan2
- ACACB | c.3823G>A p.D1275N | Missense Mutation (SNP) | VAF 178/339 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361682154, COSV100622930; called by muse, mutect2, varscan2
- ACSL5 | c.1930C>T p.H644Y (on ENST00000354273; = p.H700Y on NM_016234.3) | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV100634598; called by muse, mutect2, varscan2
- ACSM2A | c.616C>T p.H206Y (on ENST00000219054; = p.H127Y on NM_001308169.2) | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99525277; called by muse, mutect2, varscan2
- ACSM4 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68067131; called by muse, mutect2, varscan2
- ADA | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100596127; called by muse, mutect2, varscan2
- ADAD2 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs769891679, COSV51894773; called by muse, mutect2, varscan2
- ADAM29 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV100822024; called by muse, mutect2, varscan2
- ADAMTS6 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.363); catalogued as rs574046720, COSV58681823; called by muse, mutect2, varscan2
- ADAMTS7 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs764997049, COSV101183111; called by muse, mutect2, varscan2
- ADAMTS9 | c.2656C>T p.P886S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as rs774645224, COSV55777615; called by muse, mutect2, varscan2
- ADGRB2 | c.4451T>A p.L1484H (on ENST00000373658 / NM_001364857.2; = p.L1483H on NM_001294335.2) | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99926297; called by muse, mutect2, varscan2
- ADGRB3 | c.4127T>C p.L1376S | Missense Mutation (SNP) | VAF 65/116 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV99485222; called by muse, mutect2, varscan2
- ADGRE2 | c.2032C>T p.L678F | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs756940070, COSV100216061; called by muse, mutect2, varscan2
- ADGRG4 | c.5090C>T p.S1697L | Missense Mutation (SNP) | VAF 106/116 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV99795582, COSV99795696; called by muse, mutect2, varscan2
- ADH4 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1438535562, COSV55501948; called by muse, mutect2, varscan2
- ADH6 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 209/507 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99422181; called by muse, mutect2, varscan2
- AFDN | c.1969A>G p.T657A | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100653020; called by muse, mutect2, varscan2
- AFP | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV99890015; called by muse, mutect2, varscan2
- AGAP1 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 113/214 reads (53%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.993); catalogued as COSV100365271; called by muse, mutect2, varscan2
- AGAP2 | c.1538T>C p.V513A (on ENST00000547588 / NM_001122772.2; = p.V177A on NM_014770.4) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99223245; called by muse, mutect2, varscan2
- AGXT2 | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 74/111 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51487590, COSV99183757; called by muse, mutect2, varscan2
- AHCTF1 | c.2371C>T p.H791Y (on ENST00000366508; = p.H765Y on NM_015446.5) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100403751; called by muse, mutect2, varscan2
- AHRR | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs201569519, COSV57084895; called by muse, mutect2, varscan2
- AJAP1 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100981747; called by muse, mutect2, varscan2
- AKAP13 | c.3682C>T p.P1228S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs1567138709, COSV100773838; called by muse, mutect2, varscan2
- AKAP6 | c.4501G>A p.G1501S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV99801100; called by muse, mutect2, varscan2
- AKAP6 | c.6938G>A p.R2313Q | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs762276812, COSV55217242; called by muse, mutect2, varscan2
- AKAP9 | c.1819A>G p.K607E | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100662428; called by muse, mutect2, varscan2
- AL121899.2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV67352742; called by muse, mutect2, varscan2
- ALDH1A2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as COSV99990755; called by muse, mutect2, varscan2
- ALDH9A1 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV61341587; called by muse, mutect2, varscan2
- ALG9 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555155594, COSV101211901; called by muse, mutect2, varscan2
- ALOX5 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 61/74 reads (82%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs759403458, COSV100980071; called by muse, mutect2, varscan2
- AMDHD1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs200706449, COSV57139636, COSV99900368; called by muse, mutect2, varscan2
- AMIGO1 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100881066; called by muse, mutect2, varscan2
- ANGPT1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.15); catalogued as rs149379021, COSV52460175; called by muse, mutect2, varscan2
- ANGPTL2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs528804006, COSV99401703; called by muse, mutect2, varscan2
- ANKH | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs369168140; called by muse, mutect2, varscan2
- ANKRD22 | c.269A>T p.Y90F | Missense Mutation (SNP) | VAF 91/109 reads (83%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100905477; called by muse, mutect2, varscan2
- ANKRD28 | c.817T>C p.F273L | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.439); catalogued as COSV101080679; called by muse, mutect2, varscan2
- ANKRD34A | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100041268, COSV60162193; called by muse, mutect2, varscan2
- ANO7 | c.1019G>A p.G340E (on ENST00000274979; = p.G286E on NM_001370694.2) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51470767; called by muse, mutect2, varscan2
- ANO7 | c.1052G>A p.G351E (on ENST00000274979; = p.G297E on NM_001370694.2) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99238429; called by muse, mutect2, varscan2
- ANPEP | c.2754G>A p.L918= | Splice Region (SNP) | VAF 78/178 reads (44%) | catalogued as COSV100263096; called by muse, mutect2, varscan2
- ARHGAP17 | c.341T>A p.F114Y | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as COSV99253473; called by muse, mutect2, varscan2
- ARHGEF5 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs776839751, COSV99282847; called by mutect2, varscan2
- ARID1B | c.2496C>G p.S832R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.153); catalogued as COSV99269325; called by muse, mutect2, varscan2
- ARID3C | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99426892; called by muse, mutect2, varscan2
- ARID5A | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs749788615, COSV100673595; called by muse, mutect2, varscan2
- ARL11 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as rs776703350, COSV99949118; called by muse, mutect2, varscan2
- ARMC4 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.29); catalogued as COSV99518606; called by muse, mutect2, varscan2
- ASH1L | c.3553C>T p.P1185S | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100853430; called by muse, mutect2, varscan2
- ASH2L | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99166980; called by muse, mutect2
- ASPH | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.345); catalogued as COSV100727581; called by muse, mutect2, varscan2
- ASPHD1 | c.515_516insTGA p.G172_P173insD | In Frame Ins (INS) | VAF 40/85 reads (47%) | catalogued as COSV58096781, COSV58096877; called by mutect2, varscan2
- ATG2A | c.3183+1G>A p.X1061_splice | Splice Site (SNP) | VAF 45/126 reads (36%) | catalogued as COSV101034405, COSV65965841; called by muse, mutect2, varscan2
- ATP13A3 | c.3097T>C p.W1033R | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99757090; called by muse, mutect2, varscan2
- ATP13A5 | c.2357G>C p.R786P | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100665175; called by muse, mutect2, varscan2
- ATP6V0A1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 43/94 reads (46%) | catalogued as COSV52877573; called by muse, mutect2, varscan2
- ATP8B4 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99465641; called by muse, mutect2, varscan2
- ATRNL1 | c.3806G>A p.R1269Q | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.921); catalogued as rs782636812, COSV100370652, COSV100370799; called by muse, mutect2, varscan2
- AXDND1 | c.2941C>T p.Q981* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as rs1166235091, COSV62643787; called by muse, mutect2
- BACH2 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as rs199646582; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs376182024; called by muse, mutect2, varscan2
- BAK1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100645857; called by muse, mutect2, varscan2
- BAZ2B | c.2878C>T p.R960* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV54277103; called by muse, mutect2, varscan2
- BCAM | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 128/264 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99538748; called by muse, mutect2, varscan2
- BICC1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100874856; called by muse, mutect2, varscan2
- BMP3 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99261712; called by muse, mutect2, varscan2
- BMPER | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs267601492, COSV99779662; called by muse, mutect2, varscan2
- BPI | c.428C>T p.S143F (on ENST00000262865; = p.S139F on NM_001725.3) | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV99480667; called by muse, mutect2, varscan2
- BRAP | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT tolerated (0.32); PolyPhen benign (0.141); catalogued as COSV58156917; called by muse, mutect2, varscan2
- BRCA2 | c.3790A>G p.K1264E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as COSV101204260; called by muse, mutect2, varscan2
- BRD1 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53459198; called by muse, mutect2, varscan2
- BRD1 | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs147334124; called by muse, mutect2, varscan2
- BRWD3 | c.3421C>T p.H1141Y | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as COSV100956090; called by muse, mutect2, varscan2
- BTBD11 | c.2287T>A p.S763T (on ENST00000280758 / NM_001018072.2; = p.S300T on NM_001017523.2) | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99775864; called by muse, mutect2
- BZW2 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs753289484, COSV51757741, COSV99334599; called by muse, mutect2, varscan2
- C16orf46 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV100215329; called by muse, mutect2, varscan2
- C16orf92 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV54228206, COSV54228303; called by muse, mutect2, varscan2
- C2CD3 | c.5483C>T p.S1828F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100486756; called by muse, mutect2, varscan2
- C3 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746085199, COSV55578737, COSV99836450; called by muse, mutect2, varscan2
- C3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836684; called by muse, mutect2, varscan2
- CA8 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.988); catalogued as rs1263180581, COSV58772053; called by muse, mutect2, varscan2
- CACHD1 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99262354; called by muse, mutect2, varscan2
- CACNA1S | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs1028599438, COSV100755025; called by muse, mutect2, varscan2
- CACNA2D3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.145); catalogued as COSV99873824; called by muse, mutect2, varscan2
- CACNA2D4 | c.1161C>T p.F387= | Splice Region (SNP) | VAF 12/36 reads (33%) | catalogued as COSV54959204; called by muse, mutect2, varscan2
- CALCR | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100810555; called by muse, mutect2, varscan2
- CAMK2G | c.1350G>A p.T450= (on ENST00000423381 / NM_001367518.1; = p.T387= on NM_001222.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 71/93 reads (76%) | catalogued as COSV99989850; called by muse, mutect2, varscan2
- CAPN13 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV54429286; called by muse, mutect2, varscan2
- CASP10 | c.308A>T p.E103V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV99629077; called by muse, mutect2, varscan2
- CCDC170 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 93/176 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as COSV99498444; called by muse, mutect2, varscan2
- CCDC198 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777436221, COSV53602626; called by muse, mutect2, varscan2
- CCDC88C | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101105672; called by muse, mutect2, varscan2
- CCL22 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs752543853, COSV54660747, COSV54660927; called by muse, mutect2, varscan2
- CCR2 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 153/327 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV52748051, COSV52748581; called by muse, mutect2, varscan2
- CCR6 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as COSV59476170; called by muse, mutect2, varscan2
- CCT5 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV99725355, COSV99725442; called by muse, mutect2, varscan2
- CCT8L2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 150/221 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470361258, COSV63462543; called by muse, mutect2, varscan2
- CD1E | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs868718790, COSV63769843; called by muse, mutect2, varscan2
- CD22 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99323256; called by muse, mutect2, varscan2
- CD300LF | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1370872675, COSV56899423; called by muse, mutect2, varscan2
- CDC27 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99294900; called by muse, mutect2, varscan2
- CDC42BPG | c.3313C>T p.R1105* | Nonsense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as rs772213290, COSV61345287; called by muse, mutect2, varscan2
- CDH13 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.825); catalogued as rs369916041, COSV99231614; called by muse, mutect2, varscan2
- CDH16 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs755236039, COSV55334631; called by muse, mutect2, varscan2
- CDH18 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs766286596, COSV56963540; called by muse, mutect2, varscan2
- CDH6 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV54067736, COSV54069315; called by muse, mutect2, varscan2
- CDHR5 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.041); catalogued as rs748942695, COSV99449258; called by muse, mutect2, varscan2
- CDK1 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV100358835; called by muse, mutect2, varscan2
- CDKL5 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 119/137 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101184332; called by muse, mutect2, varscan2
- CDKL5 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 120/138 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101184333; called by muse, mutect2, varscan2
- CDRT15 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs750779822, COSV69755510; called by muse, mutect2, varscan2
- CEL | c.1351C>T p.P451S (on ENST00000673714; = p.P448S on NM_001807.6) | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100672493; called by muse, mutect2, varscan2
- CELA3A | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs147890009; called by muse, varscan2
- CENPK | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs557986609, COSV99669465; called by muse, mutect2, varscan2
- CEP126 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54825434, COSV99681070; called by muse, mutect2, varscan2
- CEP135 | c.3391C>T p.P1131S | Missense Mutation (SNP) | VAF 115/289 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.082); catalogued as COSV99954466; called by muse, mutect2, varscan2
- CFAP221 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs756457015, COSV54656647, COSV99732292; called by muse, mutect2, varscan2
- CFAP69 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100290121; called by muse, varscan2
- CHD1L | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782817356, COSV100787461; called by muse, mutect2, varscan2
- CHRDL2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99733801; called by muse, mutect2, varscan2
- CHRNA9 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100038963; called by muse, mutect2, varscan2
- CHRNB4 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 135/341 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV55717964, COSV99929375; called by muse, mutect2, varscan2
- CILK1 | c.1247C>T p.S416F (on ENST00000350082 / NM_001375397.1; = p.S409F on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV63153786; called by muse, mutect2, varscan2
- CILP2 | c.2686C>T p.H896Y | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs963424914, COSV99364715; called by muse, mutect2, varscan2
- CLCA1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746591052, COSV99322398; called by muse, mutect2, varscan2
- CLCN1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143506735, COSV58372528; ClinVar: uncertain significance; called by muse, varscan2
- CLCN1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601360, COSV58368483; called by muse, varscan2
- CLCNKA | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs370650380; called by muse, mutect2, varscan2
- CLDN4 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs782686647, COSV99936479; called by muse, mutect2, varscan2
- CLEC16A | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101278083; called by muse, mutect2, varscan2
- CLEC16A | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755516847, COSV101278086; called by muse, mutect2, varscan2
- CLIP2 | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.024); catalogued as COSV99791613; called by muse, mutect2, varscan2
- CLIP4 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV60749279; called by muse, mutect2, varscan2
- CLSTN2 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101515729, COSV71724212; called by muse, mutect2, varscan2
- CLVS1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs143211270, COSV57975512, COSV99073593; called by muse, mutect2, varscan2
- CMYA5 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV71406134; called by muse, mutect2, varscan2
- CMYA5 | c.8125C>T p.P2709S | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV101484059; called by muse, mutect2, varscan2
- CMYA5 | c.8126C>T p.P2709L | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101484061; called by muse, mutect2, varscan2
- CNKSR2 | c.2557T>C p.F853L | Missense Mutation (SNP) | VAF 63/71 reads (89%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99668619; called by muse, mutect2, varscan2
- CNTN5 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1215380044, COSV54283284, COSV54294122; called by muse, mutect2
- CNTN5 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54285848; called by muse, mutect2, varscan2
- CNTNAP4 | c.2147C>T p.S716L | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571000371, COSV56664435; called by muse, mutect2, varscan2
- CNTNAP5 | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.6); catalogued as rs377465900; called by muse, mutect2, varscan2
- CNTNAP5 | c.381G>A p.W127* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV101443595; called by muse, mutect2, varscan2
- COL11A1 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100616649, COSV62183560; called by muse, mutect2, varscan2
- COL11A2 | c.4439G>A p.G1480E (on ENST00000341947 / NM_080680.3; = p.G1373E on NM_080679.2) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100554053; called by muse, mutect2, varscan2
- COL11A2 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.503); catalogued as COSV100554055; called by muse, mutect2, varscan2
- COL1A2 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51967244, COSV99799819; called by muse, varscan2
- COL21A1 | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV99778829; called by muse, mutect2
- COL24A1 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 95/230 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993367; called by muse, mutect2
- COL3A1 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM000315, CM1512377, COSV100483071; called by muse, mutect2, varscan2
- COL3A1 | c.3605C>T p.A1202V | Missense Mutation (SNP) | VAF 109/165 reads (66%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV58586115; called by muse, mutect2, varscan2
- COL4A2 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV100847356; called by muse, mutect2, varscan2
- COL4A3 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350342816, COSV101170302; called by muse, mutect2, varscan2
- COL4A4 | c.3911G>A p.G1304D | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306904, COSV61633484; called by muse, mutect2, varscan2
- COL4A5 | c.3790+1G>A p.X1264_splice | Splice Site (SNP) | VAF 22/24 reads (92%) | catalogued as CD961925, COSV100087856; called by muse, mutect2, varscan2
- COL5A1 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs149912828; ClinVar: uncertain significance; called by muse, varscan2
- COL5A2 | c.1520G>A p.G507D | Missense Mutation (SNP) | VAF 135/466 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880371; called by muse, mutect2, varscan2
- COL8A1 | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99657789; called by muse, mutect2, varscan2
- COL8A2 | c.1619G>A p.G540D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as COSV100291196; called by muse, mutect2, varscan2
- COL8A2 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100291198; called by muse, mutect2, varscan2
- CPEB1 | c.715C>T p.R239* (on ENST00000617958; = p.R179* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as COSV99917722; called by muse, mutect2, varscan2
- CPED1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100120784; called by muse, mutect2, varscan2
- CPLANE2 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.395); catalogued as COSV100983269; called by muse, mutect2, varscan2
- CPS1 | c.4379G>A p.G1460E | Missense Mutation (SNP) | VAF 142/212 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV99243107; called by muse, mutect2, varscan2
- CPXM1 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101013738; called by muse, mutect2, varscan2
- CR2 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.822); catalogued as COSV100889647; called by muse, mutect2, varscan2
- CREB3L2 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV100381949; called by muse, mutect2, varscan2
- CSMD1 | c.2361G>A p.W787* (on ENST00000520002; = p.W786* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 43/50 reads (86%) | catalogued as COSV100148267; called by muse, mutect2, varscan2
- CSMD1 | c.1347G>T p.K449N (on ENST00000520002; = p.K448N on NM_033225.6) | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101221130, COSV68194406; called by muse, mutect2, varscan2
- CSMD2 | c.8989G>A p.D2997N | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.948); catalogued as COSV99590331; called by muse, mutect2, varscan2
- CSMD2 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99590333; called by muse, mutect2, varscan2
- CSMD2 | c.2164C>T p.L722F | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99590336; called by muse, mutect2, varscan2
- CTSW | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs372807233; called by muse, mutect2, varscan2
- CTSW | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1207624752, COSV100327380; called by muse, mutect2, varscan2
- CUZD1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59028923; called by muse, mutect2, varscan2
- CYFIP2 | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100556936; called by muse, mutect2, varscan2
- CYP3A5 | c.292T>A p.C98S | Missense Mutation (SNP) | VAF 91/199 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV99769806; called by muse, mutect2, varscan2
- CYP4F8 | c.1398G>A p.R466= | Splice Region (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100358127; called by muse, mutect2
- CYP7B1 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV59591974; called by muse, mutect2, varscan2
- CYRIB | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101310066; called by muse, mutect2, varscan2
- DAAM1 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs762190571, COSV100658427; called by muse, mutect2, varscan2
- DACH1 | c.2170G>A p.D724N (on ENST00000619232 / NM_001366712.1; = p.D470N on NM_004392.6) | Missense Mutation (SNP) | VAF 221/353 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV100498417, COSV57502868; called by muse, mutect2, varscan2
- DCC | c.3061C>T p.R1021* | Nonsense Mutation (SNP) | VAF 42/54 reads (78%) | catalogued as COSV59103256; called by muse, mutect2, varscan2
- DCLK3 | c.176C>G p.T59S | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101373983; called by muse, mutect2, varscan2
- DDX11 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV99299684; called by muse, mutect2, varscan2
- DDX43 | c.1212G>A p.M404I | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100943974; called by muse, mutect2, varscan2
- DDX60L | c.3905A>G p.N1302S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV99487649; called by muse, mutect2, varscan2
- DEF6 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100359331; called by muse, mutect2
- DENND1C | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV101200204; called by muse, mutect2, varscan2
- DENND3 | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.859); catalogued as COSV99371016; called by muse, mutect2, varscan2
- DEPDC1 | c.2060C>T p.S687F (on ENST00000456315 / NM_001114120.3; = p.S403F on NM_017779.6) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as rs1291879502, COSV100920322; called by muse, mutect2, varscan2
- DGKH | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147089288; called by muse, mutect2, varscan2
- DGKI | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV99934748; called by muse, mutect2, varscan2
- DGKI | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55935459; called by muse, mutect2, varscan2
- DHRS9 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 68/109 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as rs1335777749, COSV100513502; called by muse, mutect2, varscan2
- DIAPH3 | c.1844C>T p.P615L (on ENST00000400324 / NM_001042517.2; = p.P352L on NM_030932.3) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV99933605; called by muse, mutect2, varscan2
- DISP3 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99608704; called by muse, mutect2, varscan2
- DMBT1 | c.7447C>T p.P2483S (on ENST00000338354 / NM_001377530.1; = p.P1726S on NM_004406.3) | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs766376568, COSV100353050; called by muse, mutect2, varscan2
- DNAH11 | c.9625C>T p.P3209S | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.955); catalogued as COSV100179337; called by muse, mutect2, varscan2
- DNAH2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as COSV99318220; called by muse, mutect2, varscan2
- DNAH7 | c.3538G>A p.G1180R | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100415301; called by muse, mutect2, varscan2
- DNAH7 | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT tolerated (0.28); PolyPhen benign (0.305); catalogued as COSV56781251; called by muse, mutect2, varscan2
- DNAH8 | c.4777G>A p.E1593K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100545504; called by muse, mutect2, varscan2
- DNAH8 | c.10759G>A p.G3587R | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545505; called by muse, mutect2, varscan2
- DNAH9 | c.6586C>T p.P2196S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs1309351740, COSV99305967; called by muse, mutect2, varscan2
- DNAI3 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV54005975; called by muse, mutect2, varscan2
- DNM3 | c.2485G>A p.G829R (on ENST00000355305 / NM_001350206.2; = p.G823R on NM_015569.5) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs774656112, COSV62470173; called by muse, mutect2, varscan2
- DOHH | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs770738930, COSV99171021; called by muse, varscan2
- DOK4 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV99538333; called by muse, mutect2, varscan2
- DRD2 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); catalogued as COSV100669682; called by muse, mutect2, varscan2
- DRGX | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV65137571; called by muse, mutect2, varscan2
- DSC1 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs267605150, COSV99937667; called by muse, mutect2, varscan2
- DSC1 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as rs865860727, COSV99937673; called by muse, mutect2, varscan2
- DSC2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV51863565, COSV99199653; called by muse, mutect2, varscan2
- DSCAM | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 221/258 reads (86%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as rs752097825, COSV101260255; called by muse, mutect2, varscan2
- DSG4 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57390916; called by muse, mutect2, varscan2
- DSG4 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1244455121, COSV57389442; called by muse, mutect2, varscan2
- DTL | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100877216; called by muse, mutect2, varscan2
- DTL | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs768119065, COSV65342315; called by muse, mutect2, varscan2
- DYM | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV99493229; called by muse, mutect2, varscan2
- DYM | c.656del p.L219Yfs*35 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | catalogued as CM030291; called by mutect2, pindel, varscan2
- DYSF | c.6226G>A p.V2076M | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV99247341; called by muse, mutect2, varscan2
- EDNRA | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV100163393; called by muse, mutect2, varscan2
- EEF1A1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100303324, COSV58550386; called by muse, mutect2, varscan2
- EEF1G | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV100240383; called by muse, mutect2, varscan2
- EFHB | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55550576; called by muse, mutect2, varscan2
- EIF4B | c.278C>G p.S93W | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100016811; called by muse, mutect2, varscan2
- ELAPOR2 | c.2414C>T p.P805L (on ENST00000450689 / NM_001142749.3; = p.P638L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs1157257067, COSV99788828; called by muse, mutect2, varscan2
- ENPP4 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs775632459, COSV58090385; called by muse, mutect2, varscan2
- EP400 | c.3112C>T p.R1038W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1237977644, COSV100201269; called by muse, mutect2, varscan2
- EPB41L2 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 87/180 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs1458721147, COSV100440697; called by muse, mutect2, varscan2
- EPHA10 | c.720C>A p.C240* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as rs1222128985, COSV100139959, COSV57624304; called by muse, mutect2, varscan2
- EPHA3 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | catalogued as rs774448099, COSV60696980, COSV60729273; called by muse, mutect2, varscan2
- EPPK1 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101599849; called by muse, mutect2, varscan2
- ERICH3 | c.4184G>A p.G1395E | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV58612261; called by muse, mutect2, varscan2
- ERICH3 | c.3450A>T p.K1150N | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100444448; called by muse, mutect2, varscan2
- ERICH3 | c.3449A>C p.K1150T | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV100444449; called by muse, mutect2, varscan2
- ERN2 | c.1747G>A p.G583R | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV99891572; called by muse, mutect2, varscan2
- ETV7 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs758954266, COSV100339203; called by muse, varscan2
- ETV7 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV100339204; called by muse, varscan2
- EYA1 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 118/285 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100379467; called by muse, mutect2, varscan2
- F10 | c.667A>C p.T223P | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100979205; called by muse, mutect2, varscan2
- F11 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM097407, COSV53007574; called by muse, mutect2, varscan2
- F2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 69/78 reads (88%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs777315807, COSV61315666; called by muse, mutect2, varscan2
- F5 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs763040898, COSV100889110; called by muse, varscan2
- F5 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as COSV100889111, COSV63127279; called by muse, mutect2, varscan2
- FAAP100 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs771374171, COSV59883929; called by muse, mutect2, varscan2
- FAF1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 34/56 reads (61%) | catalogued as rs1409254771, COSV100875624; called by muse, mutect2, varscan2
- FAM114A1 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV100729320; called by muse, mutect2, varscan2
- FAM13A | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 84/201 reads (42%) | catalogued as rs1267942352, COSV99983732; called by muse, mutect2, varscan2
- FAM153A | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs754181660; called by muse, mutect2, varscan2
- FAM234A | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1213559592, COSV99395806; called by muse, mutect2, varscan2
- FAM83B | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.5); catalogued as COSV60921404; called by muse, mutect2, varscan2
- FAM90A1 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV100274325; called by muse, mutect2, varscan2
- FANCD2 | c.3470C>T p.S1157F | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs1213183203, COSV55032842; called by muse, mutect2, varscan2
- FAT3 | c.4460G>A p.R1487K | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as rs1421750495, COSV99965161; called by muse, mutect2, varscan2
- FAT3 | c.8068T>A p.S2690T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99966458; called by muse, mutect2, varscan2
- FAT3 | c.12122C>T p.S4041L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs771010983, COSV99966459; called by muse, mutect2, varscan2
- FAT4 | c.5302G>A p.D1768N | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100628699; called by muse, mutect2, varscan2
- FAT4 | c.13675G>A p.D4559N | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100628704; called by muse, mutect2, varscan2
- FCAMR | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs375632066, COSV61367607; called by muse, mutect2, varscan2
- FCRL1 | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100839792; called by muse, mutect2, varscan2
- FCRL6 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.191); catalogued as COSV100220199; called by muse, mutect2, varscan2
- FER1L6 | c.2619G>A p.W873* | Nonsense Mutation (SNP) | VAF 179/382 reads (47%) | catalogued as COSV67550687; called by muse, mutect2, varscan2
- FERMT1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as CM040275, COSV99451607; called by muse, mutect2, varscan2
- FERMT2 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as rs987671172, COSV58404894; called by muse, mutect2, varscan2
- FKBP5 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100616216; called by muse, mutect2, varscan2
- FLNB | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55894637, COSV55897250; called by muse, mutect2, varscan2
- FMN2 | c.3556C>T p.P1186S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.613); catalogued as rs369075397; called by muse, mutect2, varscan2
- FMO3 | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100882456; called by muse, mutect2, varscan2
- FN1 | c.4133G>A p.W1378* | Nonsense Mutation (SNP) | VAF 32/50 reads (64%) | catalogued as COSV100117192; called by muse, mutect2, varscan2
- FNDC1 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs770212056, COSV99795875; called by muse, mutect2, varscan2
- FOCAD | c.4604G>A p.G1535E | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (1); PolyPhen possibly damaging (0.888); catalogued as COSV100620441; called by muse, mutect2, varscan2
- FOXJ3 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100691833; called by muse, mutect2, varscan2
- FPR1 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 44/114 reads (39%) | catalogued as rs373383845, COSV59051979; called by muse, mutect2, varscan2
- FSCN3 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99757172; called by muse, mutect2, varscan2
- FSIP2 | c.19351C>T p.P6451S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100555261; called by muse, mutect2, varscan2
- FSTL5 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV60197809; called by muse, mutect2, varscan2
- FSTL5 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV60216744; called by muse, mutect2, varscan2
- FYB1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs760474346, COSV60947713; called by muse, mutect2, varscan2
- FYB2 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.541); catalogued as rs1182070598, COSV100599556; called by muse, mutect2, varscan2
- GABRG1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV54950313; called by muse, mutect2, varscan2
- GABRG2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868720581, COSV62721015; called by muse, mutect2, varscan2
- GABRG2 | c.1126G>A p.D376N (on ENST00000361925 / NM_001375343.1; = p.D336N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/117 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV62718109; called by muse, mutect2, varscan2
- GAL3ST3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100360876; called by muse, mutect2, varscan2
- GALNT17 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV100354030; called by muse, mutect2, varscan2
- GALNT8 | c.344A>G p.Q115R | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs780926406, COSV99362843; called by muse, mutect2, varscan2
- GALNTL6 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101560283; called by muse, mutect2, varscan2
- GANAB | c.2672G>A p.R891Q | Missense Mutation (SNP) | VAF 178/411 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs775692598, COSV55489539; called by muse, mutect2, varscan2
- GAS2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs1205756000, COSV99535117; called by muse, mutect2, varscan2
- GASK1B | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as COSV99647637; called by muse, mutect2, varscan2
- GCN1 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV100325312; called by muse, mutect2, varscan2
- GDF3 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100325278; called by muse, mutect2, varscan2
- GFPT2 | c.1939G>A p.G647S | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.79); catalogued as rs1188172744, COSV99517697; called by muse, mutect2, varscan2
- GGH | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.234); catalogued as COSV99478862; called by muse, mutect2, varscan2
- GIMAP6 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100188244; called by muse, mutect2, varscan2
- GIMAP6 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 140/336 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV61032721; called by muse, mutect2, varscan2
- GIMAP6 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as rs529185042, COSV100188247, COSV61034031; called by muse, mutect2, varscan2
- GIPC1 | c.466T>G p.F156V | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100600086; called by muse, mutect2, varscan2
- GOLGB1 | c.3773C>T p.S1258F | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV100510905; called by muse, mutect2, varscan2
- GPR158 | c.2199G>A p.M733I | Missense Mutation (SNP) | VAF 104/134 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100893600, COSV66276621; called by muse, mutect2, varscan2
- GPR180 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100979042; called by muse, mutect2, varscan2
- GRAMD1C | c.1090+2T>C p.X364_splice | Splice Site (SNP) | VAF 30/75 reads (40%) | catalogued as COSV100822912; called by muse, mutect2, varscan2
- GRAMD2B | c.679A>G p.N227D | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV99587080; called by muse, mutect2, varscan2
- GRID2 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV56174151, COSV56263047; called by muse, mutect2, varscan2
- GRIN2B | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101663050; called by muse, mutect2, varscan2
- GRIN3A | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62452298, COSV62458577; called by muse, mutect2, varscan2
- GRK4 | c.224C>T p.P75L (on ENST00000398052 / NM_182982.3; = p.P43L on NM_005307.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV100584053; called by muse, mutect2, varscan2
- GRK6 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100586905; called by muse, mutect2, varscan2
- GRM3 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.88); PolyPhen benign (0.155); catalogued as COSV64471988; called by muse, mutect2, varscan2
- HCLS1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs777497001, COSV100100679; called by muse, mutect2, varscan2
- HCN1 | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); catalogued as COSV57523526; called by muse, mutect2, varscan2
- HCN3 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746576195, COSV100712913; called by muse, mutect2, varscan2
- HECTD4 | c.7849A>T p.T2617S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.465); catalogued as COSV101107585; called by muse, mutect2, varscan2
- HELQ | c.3144G>T p.R1048S | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99787712; called by muse, mutect2, varscan2
- HERC1 | c.7714A>C p.K2572Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV101496584; called by muse, mutect2, varscan2
- HERC1 | c.6820G>A p.E2274K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.971); catalogued as COSV101496585; called by muse, mutect2, varscan2
- HGD | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99380980; called by muse, mutect2, varscan2
- HIRA | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99600383; called by muse, mutect2, varscan2
- HIVEP1 | c.4234C>T p.R1412* | Nonsense Mutation (SNP) | VAF 62/160 reads (39%) | catalogued as COSV101045158; called by muse, mutect2, varscan2
- HIVEP1 | c.5405T>C p.V1802A | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV101045159; called by muse, mutect2, varscan2
- HLA-B | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs281864640, COSV101318075, COSV69520833; called by muse, mutect2, varscan2
- HNF1A | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV99982581; called by muse, mutect2, varscan2
- HNF4G | c.53G>A p.R18K (on ENST00000354370 / NM_001330561.2; = p.R65K on NM_004133.5) | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.57); catalogued as COSV100584523; called by muse, mutect2, varscan2
- HNF4G | c.263G>A p.R88K (on ENST00000354370 / NM_001330561.2; = p.R135K on NM_004133.5) | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as COSV100584375, COSV62970975; called by muse, mutect2, varscan2
- HOATZ | c.478G>A p.E160K (on ENST00000375618 / NM_001100388.1; = p.E187K on NM_207430.2) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100239480, COSV60442552; called by muse, mutect2, varscan2
- HPS5 | c.1208C>T p.S403F (on ENST00000349215 / NM_181507.2; = p.S289F on NM_007216.4) | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100752288; called by muse, mutect2, varscan2
- HRG | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772500244, COSV99214815; called by muse, mutect2, varscan2
- HS3ST5 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV100450931, COSV57147634; called by muse, mutect2, varscan2
- HSD3B2 | c.1035G>A p.W345* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as COSV101027486; called by muse, mutect2, varscan2
- HSP90AB1 | c.2153C>T p.S718F | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99241137; called by muse, varscan2
- HSPG2 | c.8302C>T p.P2768S | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV101020704; called by muse, mutect2, varscan2
- HYDIN | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs866201822, COSV55478832; called by muse, mutect2, varscan2
- IDO1 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV99503359; called by muse, mutect2, varscan2
- IFNAR1 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.837); catalogued as COSV99531652; called by muse, mutect2, varscan2
- IFT122 | c.3623C>T p.P1208L (on ENST00000348417 / NM_052989.3; = p.P1149L on NM_018262.4) | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs773557692, COSV99959351; called by muse, mutect2, varscan2
- IFT172 | c.3082C>T p.L1028F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99562563; called by muse, mutect2, varscan2
- IFT43 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV53138238; called by muse, mutect2, varscan2
- IGFL1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.042); catalogued as rs769434804, COSV71443704; called by muse, mutect2, varscan2
- IGSF10 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99180286; called by muse, mutect2, varscan2
- IGSF8 | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs150306822; called by muse, mutect2
- IGSF8 | c.1835A>T p.K612I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV100081667; called by muse, mutect2
- IL17RC | c.1244C>T p.P415L (on ENST00000295981 / NM_153461.4; = p.P329L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs151311782; called by muse, mutect2, varscan2
- IL17RE | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.205); catalogued as rs1559266265, COSV99925022; called by muse, mutect2, varscan2
- IL36B | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.207); catalogued as rs749951364, COSV52086162, COSV52086587; called by muse, mutect2, varscan2
- INHBC | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV100548019; called by muse, mutect2, varscan2
- INO80D | c.2383C>T p.Q795* | Nonsense Mutation (SNP) | VAF 86/265 reads (32%) | catalogued as COSV101305846; called by muse, mutect2, varscan2
- INSYN1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101138776; called by muse, mutect2, varscan2
- IQCN | c.2148G>A p.M716I | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101148670; called by muse, mutect2, varscan2
- ITGA3 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 133/321 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs773119211, COSV99143685; called by muse, mutect2, varscan2
- ITGB3 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV101457617; called by muse, mutect2, varscan2
- JAK1 | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV100691754; called by muse, mutect2, varscan2
- JCAD | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948369; called by muse, mutect2
- JUP | c.1724T>A p.M575K | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV100159585; called by muse, mutect2, varscan2
- KCND2 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.003); catalogued as rs1324584742, COSV100476003; called by muse, mutect2, varscan2
- KCNH1 | c.1321G>A p.E441K (on ENST00000271751 / NM_172362.3; = p.E414K on NM_002238.4) | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.297); catalogued as COSV99659369; called by muse, mutect2, varscan2
- KCNH6 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.593); catalogued as COSV100121061; called by muse, mutect2, varscan2
- KCNH6 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as COSV59002581; called by muse, mutect2, varscan2
- KCNH8 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100109913; called by muse, mutect2, varscan2
- KCNIP4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs1393043312, COSV62845882; called by muse, mutect2, varscan2
- KCNK4 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100107754; called by muse, mutect2, varscan2
- KIAA0895L | c.570G>A p.Q190= | Splice Region (SNP) | VAF 34/84 reads (40%) | catalogued as COSV99220515; called by muse, mutect2, varscan2
- KIAA1217 | c.5653G>A p.G1885S | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100286684; called by muse, mutect2, varscan2
- KIAA1217 | c.5654G>A p.G1885D | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100286685; called by muse, mutect2, varscan2
- KIF4B | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.882); catalogued as rs541398809, COSV70528412; called by muse, mutect2, varscan2
- KIR2DL4 | c.773G>A p.G258E (on ENST00000396284; = p.G219E on NM_001080770.2) | Missense Mutation (SNP) | VAF 173/478 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV100610610; called by muse, varscan2
- KIR3DL1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 197/482 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as rs1304651125; called by muse, mutect2, varscan2
- KIR3DL2 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 212/519 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99552082, COSV99552152; called by muse, mutect2, varscan2
- KLF3 | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV99789783; called by muse, mutect2, varscan2
- KLHL23 | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 178/293 reads (61%) | catalogued as COSV99775833; called by muse, mutect2, varscan2
- KMT2A | c.4058T>G p.I1353S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100628918; called by muse, mutect2, varscan2
- KMT2B | c.6413dup p.A2139Gfs*6 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | catalogued as rs754806477; called by mutect2, varscan2
- KRTAP4-12 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 73/175 reads (42%) | catalogued as COSV101224275; called by muse, mutect2, varscan2
- KRTAP5-10 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.394); catalogued as rs749141269, COSV64794446; called by muse, varscan2
- LAD1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1208779214, COSV100943772; called by muse, mutect2, varscan2
- LAMB1 | c.4649G>A p.R1550Q | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV55963674, COSV99740715; called by muse, mutect2, varscan2
- LAMB2 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 50/108 reads (46%) | catalogued as rs947153192, COSV100565200; called by muse, mutect2, varscan2
- LARP1 | c.2480C>T p.P827L (on ENST00000518297 / NM_033551.3; = p.P750L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100303791; called by muse, mutect2, varscan2
- LARS1 | c.3469C>T p.H1157Y (on ENST00000394434 / NM_020117.11; = p.H1130Y on NM_016460.3) | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99198614; called by muse, mutect2, varscan2
- LCT | c.2633C>T p.S878F | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99929558; called by muse, mutect2, varscan2
- LDHAL6A | c.681G>A p.W227* | Nonsense Mutation (SNP) | VAF 46/110 reads (42%) | catalogued as COSV99323998; called by muse, mutect2, varscan2
- LDHC | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs768339569, COSV55003669; called by muse, mutect2, varscan2
- LDLRAD4 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 52/120 reads (43%) | catalogued as COSV63338801; called by muse, mutect2, varscan2
- LEXM | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV100827616; called by muse, mutect2, varscan2
- LHB | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99669016; called by muse, mutect2, varscan2
- LIMCH1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs377729580; called by muse, mutect2, varscan2
- LIN28A | c.32-1G>A p.X11_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99575344; called by muse, mutect2, varscan2
- LMOD2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71755639; called by muse, mutect2, varscan2
- LMOD3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1176521918, COSV101342000, COSV70456935; called by muse, mutect2, varscan2
- LMTK2 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99806921; called by muse, mutect2, varscan2
- LNX1 | c.745G>A p.E249K (on ENST00000263925 / NM_001126328.3; = p.E153K on NM_032622.2) | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.075); catalogued as COSV55783809; called by muse, mutect2, varscan2
- LRP1B | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs779330134, COSV67281330; called by muse, mutect2, varscan2
- LRRC7 | c.3674G>A p.G1225E (on ENST00000651989 / NM_001370785.2; = p.G1192E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.855); catalogued as rs867278392, COSV99227105; called by muse, mutect2, varscan2
- LRRFIP2 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100368407; called by muse, mutect2, varscan2
- LRRIQ1 | c.4420-1G>A p.X1474_splice | Splice Site (SNP) | VAF 32/53 reads (60%) | catalogued as COSV101280405; called by muse, mutect2, varscan2
- LRRK1 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV99440262; called by muse, mutect2, varscan2
- LRRK2 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV100110271; called by muse, mutect2, varscan2
- LRTM1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99836057; called by muse, mutect2, varscan2
- LRTM1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV55540705; called by muse, mutect2, varscan2
- LY9 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372951907, COSV54434246; called by muse, mutect2, varscan2
- MAB21L1 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412280293, COSV100080492; called by muse, mutect2, varscan2
- MACC1 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100255840; called by muse, mutect2, varscan2
- MACROH2A2 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100952338; called by muse, mutect2, varscan2
- MACROH2A2 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100952339; called by muse, mutect2, varscan2
- MCF2 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58476992; called by muse, mutect2, varscan2
- MCHR2 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV56004049; called by muse, mutect2, varscan2
- MCPH1 | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV100765767; called by muse, mutect2, varscan2
- MDGA1 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99776935; called by muse, mutect2, varscan2
- MECOM | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.094); catalogued as rs757020094, COSV101527923; called by muse, mutect2, varscan2
- MGAM | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71885112, COSV71885680; called by muse, mutect2, varscan2
- MGAM | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs267601325, COSV72074086; called by muse, mutect2, varscan2
- MGAM | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72073904; called by muse, mutect2, varscan2
- MIER1 | c.557C>T p.S186F (on ENST00000355356 / NM_001077701.3; = p.S203F on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100591008; called by muse, mutect2, varscan2
- MKX | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1223669362, COSV101008548, COSV65391384; called by muse, mutect2, varscan2
- MLH1 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as COSV51622348; called by muse, mutect2, varscan2
- MMP16 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54181118; called by muse, mutect2, varscan2
- MORC1 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51730882; called by muse, mutect2, varscan2
- MORC2 | c.2228C>T p.S743F (on ENST00000397641 / NM_001303256.3; = p.S681F on NM_014941.3) | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.127); catalogued as COSV99309900; called by muse, mutect2, varscan2
- MPZL1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.04); catalogued as COSV100850355; called by muse, mutect2, varscan2
- MROH9 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100882779; called by muse, mutect2, varscan2
- MTMR2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV100656729; called by muse, mutect2, varscan2
- MTTP | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99645206; called by muse, mutect2, varscan2
- MUC16 | c.30134C>T p.S10045F | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.866); catalogued as COSV101200004; called by muse, mutect2, varscan2
- MUC16 | c.28142C>T p.T9381I | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.943); catalogued as COSV101200005, COSV67481494; called by muse, mutect2, varscan2
- MUC16 | c.26327C>T p.P8776L | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.076); catalogued as rs779676785, COSV67447364; called by muse, mutect2, varscan2
- MUC16 | c.21079G>A p.E7027K | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as COSV67450667; called by muse, mutect2, varscan2
- MUC16 | c.19628C>T p.S6543L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as COSV67458970; called by muse, mutect2, varscan2
- MUC16 | c.16937C>T p.S5646F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.46); catalogued as rs759976473, COSV67454946; called by muse, mutect2, varscan2
- MUC16 | c.11800C>T p.P3934S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV101200006; called by muse, mutect2, varscan2
- MUC5AC | c.13954G>A p.E4652K | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.01); catalogued as COSV64369469; called by muse, mutect2, varscan2
- MUC5AC | c.15847G>A p.G5283R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs887447077, COSV100611461; called by muse, mutect2, varscan2
- MUTYH | c.515C>G p.A172G | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV100588044, COSV100588285; called by muse, mutect2, varscan2
- MXRA5 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 85/103 reads (83%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV54243531; called by muse, mutect2, varscan2
- MXRA5 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.746); catalogued as rs1177020975, COSV54230234; called by muse, mutect2, varscan2
- MYBPC1 | c.1991C>T p.S664F (on ENST00000550270 / NM_206820.2; = p.S689F on NM_002465.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); catalogued as COSV100638022; called by muse, mutect2, varscan2
- MYCN | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55260551; called by muse, mutect2, varscan2
- MYH2 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV99820206; called by muse, mutect2, varscan2
- MYO16 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99193936; called by muse, mutect2, varscan2
- MYO18B | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.04); catalogued as rs757746935, COSV59136441; called by muse, mutect2, varscan2
- MYO18B | c.4413C>G p.F1471L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100123740, COSV59145924; called by muse, mutect2, varscan2
- MYO5B | c.4694G>A p.G1565E | Missense Mutation (SNP) | VAF 106/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99545061; called by muse, mutect2, varscan2
- MYOCD | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV100590801; called by muse, mutect2, varscan2
- MYOCD | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100590802; called by muse, mutect2, varscan2
- NAF1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs918377846, COSV56806172; called by muse, mutect2, varscan2
- NCAPG | c.2428G>A p.G810R | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as rs1236568142, COSV99265972; called by muse, mutect2, varscan2
- NCAPG | c.2429G>A p.G810E | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as COSV52270771, COSV99265975; called by muse, mutect2, varscan2
- NCKAP1L | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53204632, COSV53211903; called by muse, mutect2, varscan2
- NCOA6 | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.022); catalogued as COSV100750064; called by muse, mutect2, varscan2
- NEBL | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369862013, COSV101008908; called by muse, mutect2, varscan2
- NEFH | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 169/254 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs267606219, COSV100151590; called by muse, mutect2, varscan2
- NEFM | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55331216; called by muse, mutect2, varscan2
- NELL1 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100121614, COSV100122560; called by muse, mutect2, varscan2
- NEU2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99290388, COSV99290573; called by muse, mutect2, varscan2
- NFE2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.567); catalogued as COSV100380756; called by muse, mutect2, varscan2
- NKAIN2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV100863001; called by muse, mutect2, varscan2
- NKAIN3 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs201185620, COSV60659818; called by muse, varscan2
- NKD2 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.838); catalogued as COSV99724099; called by muse, mutect2, varscan2
- NLRP13 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs769247296, COSV100738262, COSV61621061; called by muse, mutect2, varscan2
- NLRP14 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100205020; called by muse, mutect2, varscan2
- NLRP14 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 101/203 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.068); catalogued as COSV55072346; called by muse, mutect2, varscan2
- NMBR | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV57800668; called by muse, mutect2, varscan2
- NME8 | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52257833; called by muse, mutect2, varscan2
- NOS1 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as COSV57606672; called by muse, mutect2, varscan2
- NOS3 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99871664; called by muse, mutect2, varscan2
- NOTCH4 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.073); catalogued as COSV100900688; called by muse, mutect2
- NR5A2 | c.491G>A p.G164E (on ENST00000367362 / NM_205860.3; = p.G118E on NM_003822.5) | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52644821; called by muse, mutect2, varscan2
- NRDC | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1288884070, COSV100703402; called by muse, mutect2, varscan2
- NT5DC2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV100195048; called by muse, mutect2, varscan2
- NUDT2 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 100/125 reads (80%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100663550; called by muse, mutect2, varscan2
- NUP98 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100262446; called by muse, mutect2, varscan2
- NYNRIN | c.5546C>T p.P1849L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101230602; called by muse, mutect2, varscan2
- OGN | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0.206); catalogued as COSV99364100; called by muse, mutect2, varscan2
- OLFML2B | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs142774017; called by muse, mutect2, varscan2
- OR10AG1 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs866761699, COSV100400175, COSV56631311; called by muse, mutect2, varscan2
- OR10K2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.632); catalogued as rs775044054, COSV100149495; called by muse, mutect2, varscan2
- OR10S1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs751315243, COSV73342936, COSV73342941; called by muse, mutect2, varscan2
- OR10Z1 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63523787, COSV63526315; called by muse, mutect2, varscan2
- OR1L1 | c.809G>A p.R270K (on ENST00000373686; = p.R220K on NM_001005236.3) | Missense Mutation (SNP) | VAF 178/208 reads (86%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.588); catalogued as COSV100542176, COSV58935647; called by muse, mutect2, varscan2
- OR1L1 | c.931C>T p.Q311* (on ENST00000373686; = p.Q261* on NM_001005236.3) | Nonsense Mutation (SNP) | VAF 139/159 reads (87%) | catalogued as COSV100542178; called by muse, mutect2, varscan2
- OR1N2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 79/92 reads (86%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV65460229; called by muse, mutect2, varscan2
- OR2A25 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs763675216, COSV68717535; called by muse, mutect2, varscan2
- OR2L2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs138166879; called by muse, mutect2, varscan2
- OR2T10 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs751956005, COSV100393712; called by muse, mutect2, varscan2
- OR2T12 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV58775820; called by muse, mutect2, varscan2
- OR4A15 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as rs1423687925, COSV59033796, COSV59035039; called by muse, mutect2, varscan2
- OR4A16 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 120/273 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as rs1389734335, COSV59041785; called by muse, mutect2, varscan2
- OR4C13 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 64/85 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1197903149, COSV101634149, COSV101634182; called by muse, mutect2, varscan2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 118/283 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR4K15 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs1473022926, COSV100521041; called by muse, mutect2, varscan2
- OR4K15 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100521043; called by muse, mutect2, varscan2
- OR4K17 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs755449310, COSV100210671; called by muse, mutect2, varscan2
- OR4K17 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); catalogued as rs1178062384, COSV100210673; called by muse, mutect2, varscan2
- OR4Q3 | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100057056, COSV59180444; called by muse, mutect2, varscan2
- OR4S2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs267602971, COSV56746047; called by muse, mutect2, varscan2
- OR51A4 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV66749047; called by muse, mutect2, varscan2
- OR51B6 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66513618; called by muse, mutect2, varscan2
- OR6B3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 183/281 reads (65%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV60113513, COSV60116413; called by muse, mutect2, varscan2
- OR6C74 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs748108823, COSV59605643; called by muse, mutect2, varscan2
- OR6N1 | c.631T>A p.F211I | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100625178; called by muse, mutect2, varscan2
- OR7A17 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.155); catalogued as COSV100541619; called by muse, mutect2, varscan2
- OR7C2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.097); catalogued as rs267605312, COSV99934530; called by muse, mutect2, varscan2
- OR7D2 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV60141285; called by muse, mutect2, varscan2
- OR8G5 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 86/170 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV100422434; called by muse, mutect2, varscan2
- OR8H3 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 112/270 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.891); catalogued as COSV100538995; called by muse, varscan2
- OR8S1 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | PolyPhen benign (0); catalogued as COSV100043577, COSV59600609; called by muse, mutect2, varscan2
- OR9A4 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101516437; called by muse, mutect2, varscan2
- OSMR | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV99953030; called by muse, mutect2, varscan2
- OTOGL | c.5146G>A p.E1716K (on ENST00000547103; = p.E1707K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.711); catalogued as COSV100087311; called by muse, mutect2, varscan2
- PABPN1L | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV99967631; called by muse, mutect2, varscan2
- PABPN1L | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as rs763507540, COSV99967632; called by muse, varscan2
- PARD3 | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1325227684, COSV100401050; called by muse, mutect2, varscan2
- PARP16 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99975491; called by muse, mutect2, varscan2
- PARP8 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99891515; called by muse, mutect2, varscan2
- PASD1 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100949385; called by muse, mutect2, varscan2
- PCDH18 | c.3364G>A p.V1122M | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754250047, COSV100787326; called by muse, varscan2
- PCDH18 | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61267754; called by muse, varscan2
- PCDH18 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV100787327; called by muse, mutect2, varscan2
- PCDH18 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 70/215 reads (33%) | catalogued as COSV100787328, COSV61267675; called by muse, mutect2, varscan2
- PCDH9 | c.2342C>T p.A781V | Missense Mutation (SNP) | VAF 129/208 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV100120954; called by muse, mutect2, varscan2
- PCDHA12 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.098); catalogued as COSV100249905; called by muse, mutect2, varscan2
- PCDHB5 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1487998791, COSV50660344, COSV50673541; called by muse, mutect2, varscan2
- PCDHGB3 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV53909353, COSV54000386; called by muse, mutect2, varscan2
- PCED1B | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354949925, COSV101423644; called by muse, mutect2
- PCLO | c.10757C>T p.P3586L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV61665506; called by muse, mutect2, varscan2
- PCLO | c.6454G>A p.E2152K | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV61636627; called by muse, mutect2, varscan2
- PCLO | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); catalogued as COSV61665619; called by muse, mutect2, varscan2
- PCNT | c.7757G>A p.S2586N | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV100855539; called by muse, mutect2
- PCNX2 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs371900215, COSV99267762; called by muse, mutect2, varscan2
- PCOLCE2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV55998143; called by muse, mutect2, varscan2
- PDGFRB | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs751904503, COSV55800810; called by muse, mutect2, varscan2
- PDILT | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.121); catalogued as COSV56701010; called by muse, mutect2, varscan2
- PDLIM3 | c.93G>A p.R31= | Splice Region (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99507602; called by muse, mutect2, varscan2
- PDYN | c.204T>A p.F68L | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99453060; called by muse, mutect2, varscan2
- PDZD9 | c.596G>A p.G199E (on ENST00000424898 / NM_001363519.1; = p.G139E on NM_173806.4) | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV99193329; called by muse, mutect2, varscan2
- PGK2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs775953760, COSV59165402; called by muse, mutect2, varscan2
- PHKA1 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59807942; called by muse, mutect2, varscan2
- PHKG1 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV99305129; called by muse, mutect2, varscan2
- PHLDB1 | c.1765C>T p.L589F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1555106831, COSV100616557; called by muse, mutect2, varscan2
- PHLDB2 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV67312569; called by muse, mutect2, varscan2
- PHTF1 | c.688C>G p.H230D | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100760113; called by muse, varscan2
- PI4KA | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99746372; called by muse, mutect2, varscan2
- PID1 | c.725C>T p.S242F (on ENST00000354069 / NM_001330156.1; = p.S240F on NM_017933.5) | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV62472576; called by muse, mutect2, varscan2
- PIGV | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as COSV99314934; called by muse, mutect2, varscan2
- PIK3C2B | c.3359T>C p.F1120S | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs147511381; called by muse, mutect2, varscan2
- PIK3C2G | c.1780C>T p.P594S (on ENST00000676171; = p.P553S on NM_004570.5) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1450872122, COSV99851710; called by muse, mutect2, varscan2
- PIK3C2G | c.2316T>C p.S772= (on ENST00000676171; = p.S731= on NM_004570.5) | Splice Region (SNP) | VAF 33/65 reads (51%) | catalogued as COSV99851714; called by muse, mutect2, varscan2
- PKD1L1 | c.3790G>A p.V1264I | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.416); catalogued as COSV99219836; called by muse, mutect2, varscan2
- PKHD1 | c.9535C>T p.L3179F | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs897671588, COSV100583205; called by muse, mutect2, varscan2
- PKHD1L1 | c.11643G>A p.W3881* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV101006166; called by muse, mutect2, varscan2
- PLA2G15 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.197); catalogued as rs777101572, COSV99547216; called by muse, mutect2, varscan2
- PLA2G4A | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs200911298, COSV66554515; called by muse, mutect2, varscan2
- PLA2G4E | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370317501; called by muse, mutect2, varscan2
- PLCB1 | c.2642G>A p.S881N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.053); catalogued as rs1231040361, COSV100571154; called by muse, mutect2, varscan2
- PLCE1 | c.4192C>T p.L1398F | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99595067; called by muse, mutect2, varscan2
- PLEKHM1 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101378746; called by muse, mutect2, varscan2
- PLOD2 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.489); catalogued as rs758538664, COSV51464268; called by muse, mutect2, varscan2
- PLS1 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as COSV61833623; called by muse, mutect2, varscan2
- PLXDC1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs755346181, COSV100195376; called by muse, varscan2
- PLXNA3 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs375643017, COSV100859992; called by muse, mutect2, varscan2
- PMFBP1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.225); catalogued as rs756969527, COSV99400929; called by muse, mutect2, varscan2
- PNPLA7 | c.2965G>A p.G989S | Missense Mutation (SNP) | VAF 107/123 reads (87%) | SIFT tolerated (0.69); PolyPhen benign (0.209); catalogued as rs1299464272, COSV99480618; called by muse, mutect2, varscan2
- PODXL2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100686407; called by muse, mutect2, varscan2
- POM121L12 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs561163138, COSV101374919; called by muse, varscan2
- POMP | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV101076867; called by muse, mutect2, varscan2
- POU5F2 | c.485C>G p.T162R | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV101232757, COSV67942524; called by muse, mutect2, varscan2
- PPEF1 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 83/92 reads (90%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs142716113, COSV62997286; called by muse, mutect2, varscan2
- PPFIA1 | c.3529C>T p.P1177S | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.206); catalogued as COSV99557466; called by muse, mutect2, varscan2
- PPFIA1 | c.3530C>T p.P1177L | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99557468; called by muse, mutect2, varscan2
- PPIC | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100120577; called by muse, mutect2, varscan2
- PPP1CA | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV56702560; called by muse, mutect2, varscan2
- PPP1R13L | c.2250C>T p.D750= | Splice Region (SNP) | VAF 32/79 reads (41%) | catalogued as rs1235757811, COSV62908654; called by muse, mutect2, varscan2
- PPP4R4 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.324); catalogued as COSV100428661; called by muse, mutect2, varscan2
- PPP6R3 | c.653T>A p.I218N | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99676501; called by muse, mutect2, varscan2
- PRAMEF1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 144/343 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147163117, COSV60006586; called by muse, mutect2, varscan2
- PRAMEF6 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 38/503 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1254347312; called by muse, mutect2
- PRDM10 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755600909, COSV58805456; called by muse, mutect2, varscan2
- PRDM9 | c.2387G>A p.R796K | Missense Mutation (SNP) | VAF 98/129 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV99690497; called by muse, varscan2
- PRELP | c.843G>T p.R281S | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV100557837; called by muse, mutect2, varscan2
- PREX2 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1478970691, COSV99907418; called by muse, mutect2, varscan2
- PRG2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100314922; called by muse, mutect2, varscan2
- PRH1 | c.496A>T p.K166* | Nonsense Mutation (SNP) | VAF 60/155 reads (39%) | catalogued as COSV101457495; called by muse, mutect2, varscan2
- PRKAG3 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99291963; called by muse, mutect2, varscan2
- PRKCQ | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 79/106 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV54106163; called by muse, mutect2, varscan2
- PRKD3 | c.245T>C p.L82S | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV99306167; called by muse, mutect2, varscan2
- PRKDC | c.8197A>T p.M2733L | Missense Mutation (SNP) | VAF 193/431 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100040763; called by muse, mutect2, varscan2
- PRKN | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as COSV58201320; called by muse, mutect2, varscan2
- PRMT5 | c.1074C>T p.V358= | Splice Region (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99362992; called by muse, mutect2, varscan2
- PROX2 | c.632A>T p.K211M | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV101507809; called by muse, mutect2, varscan2
- PRSS54 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99540966; called by muse, mutect2, varscan2
- PSG4 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 122/280 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54940861; called by muse, mutect2, varscan2
- PTH1R | c.1212G>A p.R404= | Splice Region (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100480978; called by muse, mutect2, varscan2
- PTPN13 | c.3200C>T p.S1067F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as COSV100364806; called by muse, mutect2, varscan2
- PTPN21 | c.2951T>C p.M984T | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100161955; called by muse, mutect2, varscan2
- PTPN21 | c.1442A>G p.Y481C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.855); catalogued as rs749950713, COSV100161956; called by muse, mutect2, varscan2
- PTPRK | c.2524C>T p.R842C (on ENST00000368215 / NM_001291984.2; = p.R843C on NM_002844.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.353); catalogued as rs201848981, COSV63890823; called by muse, mutect2, varscan2
- PTPRT | c.2769C>T p.S923= | Splice Region (SNP) | VAF 80/204 reads (39%) | catalogued as COSV100627460; called by muse, mutect2, varscan2
- PYGM | c.2254T>A p.S752T | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV99377154; called by muse, mutect2, varscan2
- RAF1 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs755384884, COSV99312621; called by muse, mutect2, varscan2
- RANBP3L | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV99683746, COSV99683824; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs375234077; called by muse, varscan2
- RASSF6 | c.299G>A p.R100Q (on ENST00000342081 / NM_201431.2; = p.R68Q on NM_177532.5) | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs1302260242, COSV100274920; called by muse, mutect2, varscan2
- RBM12B | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 152/316 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs751630925, COSV67897416, COSV67897485; called by muse, mutect2, varscan2
- RERE | c.4570T>C p.S1524P | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100556378; called by muse, mutect2, varscan2
- RFX3 | c.1087-1G>A p.X363_splice | Splice Site (SNP) | VAF 26/29 reads (90%) | catalogued as COSV100175168; called by muse, mutect2, varscan2
- RGL2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV101004788; called by muse, mutect2, varscan2
- RIMS2 | c.883G>A p.D295N (on ENST00000666250 / NM_001348490.2; = p.D103N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.895); catalogued as rs1469042326, COSV51657475; called by muse, mutect2, varscan2
- RIPK4 | c.2356G>A p.A786T (on ENST00000352483; = p.A738T on NM_020639.3) | Missense Mutation (SNP) | VAF 106/121 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs369156558; called by muse, mutect2, varscan2
- RIPOR3 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV99246528; called by muse, mutect2, varscan2
- RIT2 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 159/340 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56297770; called by muse, mutect2, varscan2
- RNF17 | c.3991C>T p.P1331S | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV99693286; called by muse, mutect2, varscan2
- RNF40 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as COSV100222108; called by muse, mutect2, varscan2
- ROBO2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868459806, COSV59908612; called by muse, mutect2, varscan2
- RORC | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59093290; called by muse, mutect2, varscan2
- RPGRIP1 | c.2252G>A p.W751* | Nonsense Mutation (SNP) | VAF 20/31 reads (65%) | catalogued as COSV99251088; called by muse, mutect2, varscan2
- RPS6KC1 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100873910; called by muse, mutect2, varscan2
- RSF1 | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771791885, COSV100407095; called by muse, mutect2, varscan2
- RSRC1 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as rs768465194, COSV99906240; called by muse, mutect2, varscan2
- RUBCNL | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100529094; called by muse, mutect2, varscan2
- RUNX1T1 | c.248C>G p.S83C (on ENST00000265814 / NM_001198628.1; = p.S56C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99752201; called by muse, mutect2, varscan2
- RUSC2 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs749394429, COSV63429765; called by muse, mutect2, varscan2
- RYR2 | c.12139G>A p.D4047N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100770403; called by muse, mutect2, varscan2
- SAGE1 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 78/90 reads (87%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.74); catalogued as COSV61015247; called by muse, mutect2, varscan2
- SALL3 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs1223857474, COSV73306570; called by muse, mutect2, varscan2
- SCAF1 | c.3868C>T p.P1290S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.785); catalogued as COSV100566949; called by muse, mutect2, varscan2
- SCAP | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768447765, COSV55560369; called by muse, mutect2, varscan2
- SCN10A | c.5060G>A p.G1687D | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as rs971950651, COSV101479401, COSV71861348; called by muse, mutect2, varscan2
- SCN2A | c.4351C>T p.L1451F | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV99331830; called by muse, mutect2, varscan2
- SDR16C5 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV58126211; called by muse, mutect2, varscan2
- SEC14L5 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778316449, COSV52039575; called by muse, mutect2, varscan2
- SEC63 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397096640, COSV100938393; called by muse, mutect2, varscan2
- SELENBP1 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64372872; called by muse, mutect2, varscan2
- SEMA3D | c.1704G>A p.R568= | Splice Region (SNP) | VAF 46/96 reads (48%) | catalogued as COSV99406686; called by muse, mutect2, varscan2
- SEMA3D | c.313-1G>A p.X105_splice | Splice Site (SNP) | VAF 27/62 reads (44%) | catalogued as COSV52386752, COSV52406823, COSV99406687; called by muse, mutect2, varscan2
- SEMG2 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs867936565, COSV65647922; called by muse, mutect2, varscan2
- SERPINI2 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52985325; called by muse, mutect2, varscan2
- SERTAD3 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.234); catalogued as COSV100475110; called by muse, mutect2, varscan2
- SESTD1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.097); catalogued as rs1317723084, COSV70568919; called by muse, mutect2, varscan2
- SETBP1 | c.3180G>A p.M1060I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.31); catalogued as COSV56312797; called by muse, mutect2, varscan2
- SEZ6 | c.1311C>A p.Y437* | Nonsense Mutation (SNP) | VAF 94/224 reads (42%) | catalogued as COSV100253125; called by muse, mutect2, varscan2
- SGK1 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV99398335; called by muse, mutect2, varscan2
- SHC4 | c.772T>C p.S258P | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100194632; called by muse, mutect2, varscan2
- SHQ1 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV57767589; called by muse, mutect2
- SHROOM4 | c.3298C>T p.P1100S | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99173565; called by muse, mutect2, varscan2
- SLC16A2 | c.361G>T p.V121F | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99330706; called by muse, mutect2, varscan2
- SLC18A1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV99368602; called by muse, mutect2, varscan2
- SLC25A52 | c.262C>T p.R88* (on ENST00000672005; = p.R78* on NM_001034172.4) | Nonsense Mutation (SNP) | VAF 68/141 reads (48%) | catalogued as COSV52502938; called by muse, mutect2, varscan2
- SLC2A11 | c.203C>T p.S68F (on ENST00000345044 / NM_001024938.4; = p.S75F on NM_030807.5) | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99741462; called by muse, mutect2, varscan2
- SLC36A2 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV100079160; called by muse, mutect2, varscan2
- SLC4A1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs777378002, COSV99293360; called by muse, mutect2, varscan2
- SLC4A8 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV60654471; called by muse, mutect2, varscan2
- SLC5A8 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73310725; called by muse, mutect2, varscan2
- SLC9A3 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.656); catalogued as rs375784344; called by muse, mutect2, varscan2
- SLC9A5 | c.679T>C p.F227L | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100237322, COSV55365381; called by muse, mutect2, varscan2
- SLFN12 | c.1619G>C p.R540T | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs750632997, COSV59225123, COSV59226799; called by muse, mutect2, varscan2
- SLITRK3 | c.2356G>A p.G786R | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.419); catalogued as COSV99579288; called by muse, mutect2, varscan2
- SLX4IP | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 60/135 reads (44%) | catalogued as COSV100570526; called by muse, mutect2, varscan2
- SMG8 | c.1921T>G p.C641G | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99958845; called by muse, mutect2, varscan2
- SMYD1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV101352447; called by muse, mutect2, varscan2
- SNAPC4 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 190/214 reads (89%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs762765935, COSV53731272; called by muse, mutect2, varscan2
- SNX31 | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100310160; called by muse, mutect2, varscan2
- SORBS2 | c.1936C>T p.H646Y | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99511099; called by muse, mutect2, varscan2
- SORCS3 | c.1302+1G>A p.X434_splice | Splice Site (SNP) | VAF 53/56 reads (95%) | catalogued as rs1194332283, COSV63816433; called by muse, mutect2, varscan2
- SORCS3 | c.3133C>T p.L1045F | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100865153, COSV100865640, COSV63830189; called by muse, mutect2, varscan2
- SOX30 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV99398466; called by muse, mutect2, varscan2
- SOX30 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs375931805; called by muse, mutect2, varscan2
- SP140 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs765460715, COSV59448176; called by muse, mutect2, varscan2
- SP140 | c.1907G>A p.R636K | Missense Mutation (SNP) | VAF 75/131 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.727); catalogued as rs1378784167, COSV100613813; called by muse, mutect2, varscan2
- SPART | c.1299G>T p.W433C | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768745; called by muse, mutect2, varscan2
- SPATA5 | c.1565G>C p.G522A | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs766500233, COSV99915516; called by muse, mutect2, varscan2
- SPOCK1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.091); catalogued as COSV99969121; called by muse, mutect2, varscan2
- SPON1 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as COSV100115899; called by muse, mutect2, varscan2
- SPTBN1 | c.4586C>T p.T1529I | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV100442665; called by muse, mutect2, varscan2
- SPTBN2 | c.4555G>A p.D1519N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV59462110; called by muse, mutect2, varscan2
- SPTLC3 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs267605838, COSV65463320; called by muse, mutect2, varscan2
- SRI | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99719805; called by muse, mutect2, varscan2
- SRL | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as rs1295137726, COSV68423078; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 62/159 reads (39%) | PolyPhen probably damaging (0.943); catalogued as rs1249255169, COSV100083364; called by muse, mutect2, varscan2
- STAR | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 57/66 reads (86%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV52418976; called by muse, mutect2, varscan2
- STEAP2 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs748377577, COSV99840440; called by muse, mutect2, varscan2
- STK19 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV61712750; called by muse, mutect2, varscan2
- STK31 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63454235; called by muse, mutect2, varscan2
- STXBP5 | c.1924G>A p.G642R | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV99470312; called by muse, mutect2, varscan2
- SUPT16H | c.2316G>A p.M772I | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV99359888; called by muse, mutect2, varscan2
- SVEP1 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV100238054, COSV57033053; called by muse, mutect2, varscan2
- SVIL | c.4039G>A p.E1347K (on ENST00000355867 / NM_021738.3; = p.E921K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV63442036; called by muse, mutect2
- SYCP1 | c.2429T>C p.L810S | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1462165311, COSV101050945; called by muse, mutect2, varscan2
- SYNE1 | c.26249C>T p.P8750L (on ENST00000367255 / NM_182961.4; = p.P8702L on NM_033071.3) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99565244; called by muse, mutect2, varscan2
- SYNE1 | c.15907C>T p.R5303W (on ENST00000367255 / NM_182961.4; = p.R5232W on NM_033071.3) | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs149215868; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SYNJ1 | c.4775C>T p.P1592L | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV100449327; called by muse, mutect2, varscan2
- TAS2R39 | c.670T>C p.F224L | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV71470950; called by muse, mutect2, varscan2
- TAS2R9 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.388); catalogued as rs1188195486, COSV99553797; called by muse, mutect2, varscan2
- TAT | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100587637, COSV63533161; called by muse, mutect2, varscan2
- TBC1D10C | c.115C>A p.R39S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV100408234; called by muse, mutect2, varscan2
- TBC1D4 | c.3448G>A p.D1150N | Missense Mutation (SNP) | VAF 61/82 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.246); catalogued as COSV100884611, COSV66491696; called by muse, mutect2, varscan2
- TBC1D8B | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 45/47 reads (96%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.822); catalogued as COSV99344434; called by muse, mutect2, varscan2
- TBC1D8B | c.3020C>T p.P1007L | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV99344437; called by muse, mutect2, varscan2
- TBR1 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV67419742; called by muse, mutect2, varscan2
- TBX18 | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV63736236; called by muse, mutect2, varscan2
- TCEAL5 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 69/77 reads (90%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV101013107, COSV65503486; called by muse, mutect2, varscan2
- TCERG1 | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99694844; called by muse, mutect2, varscan2
- TCTE1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV101025441; called by muse, mutect2, varscan2
- TECPR2 | c.1708A>G p.M570V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV100850009; called by muse, mutect2, varscan2
- TENM1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64425119; called by muse, mutect2, varscan2
- TENM4 | c.8160G>A p.W2720* | Nonsense Mutation (SNP) | VAF 58/128 reads (45%) | catalogued as COSV99574987; called by muse, mutect2, varscan2
- TENM4 | c.5125C>T p.P1709S | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs371313766; called by muse, mutect2, varscan2
- TENT5B | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 83/197 reads (42%) | catalogued as COSV100006637; called by muse, mutect2, varscan2
- TEX15 | c.5521G>A p.D1841N (on ENST00000256246; = p.D2224N on NM_001350162.2) | Missense Mutation (SNP) | VAF 72/90 reads (80%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99821393; called by muse, mutect2, varscan2
- TEX15 | c.5242C>T p.Q1748* (on ENST00000256246; = p.Q2131* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 27/31 reads (87%) | catalogued as COSV99821394; called by muse, mutect2, varscan2
- TEX15 | c.4040G>A p.G1347E (on ENST00000256246; = p.G1730E on NM_001350162.2) | Missense Mutation (SNP) | VAF 66/79 reads (84%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs866055420, COSV56341603; called by muse, mutect2, varscan2
- TEX44 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1216944729, COSV100009749; called by muse, mutect2, varscan2
- TGM2 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs755986044, COSV100821632; called by muse, mutect2, varscan2
- TIAM1 | c.3551C>T p.S1184L | Missense Mutation (SNP) | VAF 100/127 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54544172; called by muse, mutect2, varscan2
- TMEM101 | c.321C>T p.V107= | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as COSV99243820; called by muse, mutect2, varscan2
- TMEM132D | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs1442103827, COSV101242857; called by muse, mutect2, varscan2
- TMEM145 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV99236472; called by muse, mutect2, varscan2
- TMEM198 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs146753639; called by muse, mutect2, varscan2
- TMEM92 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 129/370 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100305148; called by muse, mutect2, varscan2
- TMPRSS11B | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.738); catalogued as COSV60292468; called by muse, mutect2, varscan2
- TNFRSF21 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV99729673; called by muse, mutect2, varscan2
- TNFSF13B | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); catalogued as COSV101022355, COSV65517126; called by muse, mutect2, varscan2
- TNN | c.2403A>T p.Q801H | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.389); catalogued as COSV99512037; called by muse, mutect2, varscan2
- TNPO1 | c.2610T>A p.N870K | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV100473472; called by muse, mutect2, varscan2
- TNS1 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99410806; called by muse, mutect2, varscan2
- TNXB | c.8272G>A p.E2758K (on ENST00000647633; = p.E2511K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as COSV100926354; called by muse, mutect2, varscan2
- TOX | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100812755; called by muse, mutect2, varscan2
- TRA2A | c.336G>A p.R112= | Splice Region (SNP) | VAF 23/59 reads (39%) | catalogued as rs1235389106, COSV99767669; called by muse, mutect2, varscan2
- TRANK1 | c.7372G>A p.D2458N | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.299); catalogued as COSV100083052; called by muse, mutect2, varscan2
503 further variants in this file (83 protein-altering or splice-affecting, 395 silent, 25 other) are not listed here.
